Somatic mutation profile of tumor specimen TCGA-CH-5751-01A (aliquot TCGA-CH-5751-01A-11D-1576-08) from TCGA case TCGA-CH-5751, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.3 years (24,957 days).
Specimen TCGA-CH-5751-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f5a84ea-d4da-4734-87e6-d2945184c4b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5751-10A (Blood Derived Normal), aliquot TCGA-CH-5751-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ce37353-014f-45a6-b48c-84f4655474f1

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACY3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs752356615, COSV54828571; called by muse, mutect2, varscan2
- AKAP8L | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs768189341, COSV68473235; called by muse, mutect2, varscan2
- BBS9 | c.2456T>C p.L819S (on ENST00000242067 / NM_001348036.1; = p.L779S on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54164410; called by muse, mutect2, varscan2
- CABP4 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56886078; called by muse, mutect2, varscan2
- CYP4F2 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs140630977; called by muse, mutect2, varscan2
- DCDC2 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51239645; called by muse, mutect2, varscan2
- EPPK1 | c.4755G>T p.M1585I | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as rs111431754, COSV101599701, COSV73261073; called by muse, mutect2, varscan2
- FBXL4 | c.1649A>C p.D550A | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV57746485; called by muse, mutect2, varscan2
- KIFC1 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 46/331 reads (14%) | catalogued as COSV65728901; called by muse, varscan2
- KLHL18 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51745071; called by muse, mutect2, varscan2
- KLHL4 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs755871530, COSV64141313; called by mutect2, varscan2
- SGSH | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58339045; called by muse, mutect2, varscan2
- SLCO6A1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV65808561; called by muse, varscan2
- SOD3 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV66125640; called by muse, mutect2, varscan2
- SOWAHB | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1338078795, COSV57554335; called by muse, mutect2, varscan2
- TMPRSS7 | c.2027C>T p.P676L (on ENST00000452346; = p.P550L on NM_001042575.2) | Missense Mutation (SNP) | VAF 126/354 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.153); catalogued as rs775990921, COSV69979574, COSV69980453; called by muse, mutect2, varscan2
- TRPC6 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs201859973, COSV60253193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.79747A>C p.M26583L (on ENST00000591111; = p.M19159L on NM_003319.4) | Missense Mutation (SNP) | VAF 74/225 reads (33%) | PolyPhen benign (0); catalogued as COSV59994713; called by muse, mutect2, varscan2
- ZIC1 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV51552605, COSV99291741; called by muse, mutect2, varscan2
- ZNF24 | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54348330; called by muse, mutect2, varscan2
- DHFR | c.218_222del p.N73Sfs*22 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- ETV3 | c.287dup p.Y96* | Nonsense Mutation (INS) | VAF 41/90 reads (46%) | called by mutect2, pindel, varscan2
- DOK2 | c.612G>A p.R204= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV52388228; called by muse, mutect2, varscan2
- FUT8 | c.1593G>C p.V531= (on ENST00000360689 / NM_001371534.1; = p.V368= on NM_004480.4) | Silent (SNP) | VAF 22/231 reads (10%) | catalogued as COSV61283180; called by muse, mutect2
- KIF18A | c.2109T>C p.I703= | Silent (SNP) | VAF 53/256 reads (21%) | catalogued as COSV54182479; called by muse, mutect2, varscan2
- TMEM243 | c.33C>T p.T11= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs1227271581, COSV57538328; called by muse, mutect2, varscan2
- TRIM33 | c.861C>T p.F287= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV61822059; called by muse, mutect2
- XIST | n.11303G>A | RNA (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
